Surgical pathology report (de-identified scan), TCGA case TCGA-10-0935, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0935-01A (Primary Tumor).

[page 1 of 2]
(A) RIGHT TUBE AND OVARY:

HIGH-GRADE PAPILLARY SEROUS CARCINOMA (8.0 X 5.5 X 4.5 CM), RIGHT OVARY.
LYMPHOVASCULAR INVASION IS PRESENT.

(B) LEFT TUBE AND OVARY WITH PORTION OF COLON:

LEFT OVARY: HIGH-GRADE PAPILLARY SEROUS CARCINOMA WITH EXTENSIVE NECROSIS
(4.2 X 4.1 X 3.5 CM).

HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVADES MUSCULAR LAYER OF COLON.

SURGICAL RESECTION MARGIN POSITIVE.

PERICOLONIC TISSUE IS EXTENSIVELY INVOLVED BY THE PAPILLARY SEROUS CARCINOMA.

Two pericolic lymph nodes, no tumor present (0/2).

Left fallopian tube: Not identified.

(C) OMENTUM:

HIGH GRADE SEROUS CARCINOMA, EXTENSIVELY.

Two lymph node, no tumor present (0/2).

(D) COLON:

HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING COLON MUSCULAR LAYERS.

METASTATIC HIGH-GRADE PAPILLARY SEROUS CARCINOMA PRESENT IN SIX OF SEVEN PERICOLONIC
LYMPH NODES (6/7).

(E) PORTION OF COLON #2:

HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING COLON MUSCULAR LAYERS.

METASTATIC HIGH-GRADE PAPILLARY SEROUS CARCINOMA PRESENT IN TWO OF FIVE PERICOLONIC
LYMPH NODES (2/5).

GROSS DESCRIPTION

(A) RIGHT TUBE AND OVARY - Irregular nodular tissue, 8.0 x 5.5 x 4.5 cm. The outer surface is congested, irregular, and shaggy with adherent yellow-tan plaques. The parenchyma is friable, papillary, and pink-tan with areas of hemorrhage. No fallopian tube is identified. Representative material is submitted for tumor bank.

SECTION CODE: A1-A7, representative sections from the tumor (A1 and A2 for frozen).

*FS/DX: HIGH-GRADE PAPILLARY SEROUS CARCINOMA.

(B) LEFT TUBE AND OVARY WITH PORTION OF COLON - A specimen of ovary 8.0 x 6.0 x 4.5 cm with a tubular structure (possible fallopian tube) stretched over the surface (2.5 cm in length and 0.5 cm in width), with adherent segment of colon 8.0 cm in length and 3.0 cm in average width.

The outer surface of ovary is shaggy and irregular and is markedly congested. The ovary has multiloculated cysts filled with green-yellow tan fluid. Inside one of the cavity is a pink-tan friable papillary mass 4.2 x 4.1 x 3.5 cm.

The colonic mucosa is edematous. Representative material from tumor and normal colon is given for tumor bank.

SECTION CODE: B1-B7, tumor; B8, possible fallopian tube; B9, one side colonic resection margin; B10, other side resection margin; B11, representative colon; B12, possible lymph nodes in the pericolic adipose tissue.

(C) OMENTUM - A portion of pink-tan adipose tissue (24.0 x 4.0 x 3.0 cm). The specimen is serially sectioned and two fragments of tumor are identified (10.0 x 4.0 x 3.0 cm, 7.0 x 2.0 x 1.5 cm). Representative sections of the two tumor fragments are submitted.

SECTION CODE: C1, a representative section of the small fragment of tumor; C2-C5, representative sections of the larger fragment of tumor; C6, representative section of non-tumor tissue submitted.

[page 2 of 2]
[REDACTED]

(D) COLON - Adherent loops of colon are together measuring 7.5 x 5.5 x 3.5 cm. A firm yellow-tan gelatinous tumor is identified measuring 3.8 x 2.5 x 2.0 cm, infiltrating into the pericolic adipose tissue into the wall of the colon. The overlying mucosa is intact and edematous.

SECTION CODE: D1-D6, tumor with overlying colonic mucosa; D7-D8, multiple possible pericolic intact lymph nodes.

[REDACTED]

(E) PORTION OF COLON #2 - A segment of colon 5.0 cm in length and 3.0 cm in depth. A 2.2 x 1.8 x 1.5 cm firm yellow-tan tumor is seen infiltrating from the pericolic connective tissue into the wall of the colon. The overlying colonic mucosa is unremarkable.

SECTION CODE: E1, E2, tumor with colon; E3, one side colonic resection margin; E4, other side colonic resection margin. [REDACTED]

CLINICAL HISTORY

Ovarian cancer.

[REDACTED]

[REDACTED]

[REDACTED] en

Source: NCI Genomic Data Commons file 1c2a0893-85c3-4a4c-a150-ef4d48a1646b (TCGA-10-0935.F9111190-C01E-4FE7-A1DB-BE0434F1365F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).